CCDI case PBBZBF — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/b2fe6dd9-58ca-4e2c-9500-bc89345b6d78

Demographics
Sex at birth: male; Ethnicity: hispanic or latino.

Diagnoses (1)
1. Tumor cells, malignant: ICD-O-3 morphology code: 8001/3; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 16.1 years (5,878 days).

Biospecimens (3 samples)
- Sample 0DLBLY: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DLBMG: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DLBMQ: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
